Surgical pathology report (de-identified scan), TCGA case TCGA-WX-AA47, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Yale University, specimen TCGA-WX-AA47-01A (Primary Tumor).

[page 1 of 4]
DEPARTMENT OF
PATHOLOGY

SURGICAL PATHOLOGY REPORT

Clinical History and Impression:

female for left hepatectomy
Liver mass

Date

Specimen(s) Received:
LIVER TUMOR

*ICD-O-3
Carcinoma, hepatocellular 8170/3
Site: Liver C22.0 10/30/14*

FINAL DIAGNOSIS

LIVER, 1300 GRAMS, LEFT HEPATECTOMY:

- MODERATELY DIFFERENTIATED HEPATOCELLULAR CARCINOMA, AT LEAST 14 CM, ARISING IN A HEPATOCELLULAR ADENOMA, 17.3
- THE RESECTION MARGIN IS NEGATIVE FOR CARCINOMA; CARCINOMA IS 0.7CM FROM THE RESECTION MARGIN
- CARCINOMA INVADIES INTO THE LIVER CAPSULE
- PERICAPSULAR ORGANIZING AND FIBROUS ADHESIONS TO SMOOTH MUSCLE OF GASTRIC WALL; NO GASTRIC MUCOSA PRESENT
- NO HEPATOCELLULAR CARCINOMA IS SEEN IN THE ORGANIZING FIBROUS ADHESIONS OR THE GASTRIC WALL
- MULTI-FOCAL SMALL AND LARGE VENOUS INVASION IS PRESENT
- PATHOLOGIC TUMOR STAGE: pT3A Nx Mx Stage IIIA
- NON NEOPLASTIC LIVER
- MILD PORTAL INFLAMMATION
- NO SIGNIFICANT PORTAL FIBROSIS
- MARKED TELANGIECTASIA AND CONGESTION

MICROSCOPIC DESCRIPTION: The specimen is largely replaced by a hepatocellular neoplasm with a heterogenous appearance, grossly and histologically. The liver tumor is multinodular with areas of extensive hemorrhage and necrosis. The malignant hepatocytes are arranged in thickened cords with nuclear atypia and mitosis with some areas of classical trabecular HCC. Areas of extensive pseudoglandular architecture are also present as are areas of diffuse intracytoplasmic vacuolar inclusions, resulting in a signet ring cell like morphology. There are also extensive steatotic neoplastic hepatocytes with cytoplasmic bile inclusions as well as some malignant cells with Mallory

[page 2 of 4]
hyaline. In some of the slightly more peripheral nodules, benign hepatocytes have areas of FNH like architecture with proliferating ductules along fibrous septa. In one of these foci, a nodule of definite HCC is present. Multifocal venous invasion is seen (large and small) with at least one nodule of HCC adhering to the endothelium. Areas of the nodules lack the cytologic and architectural atypia to be considered HCC and appear to represent the background adenoma.

Immunohistochemical characterization is similarly heterogenous with areas of steatotic hepatocytes within the nodule expressing amyloid A stain while other areas with the FNH like architecture are negative for amyloid A. Glutamine synthetase has a geographic staining pattern in apparently hepatocellular adenoma like areas, with strong diffuse staining in steatotic and trabecular HCC. Glypican 3 is negative throughout, while HSP 70 is positive in trabecular HCC (focally in the same area as the glutamine synthetase).

The non-neoplastic liver has intact architecture (supported by trichrome and reticulin stains) with mild portal inflammation and patchy portal fibrosis. The lobules have marked sinusoidal dilatation and congestion without other significant inflammatory changes or steatosis. DPAS and Iron stains have no significant positivity. Hepatitis B core and surface antigen stains are negative.

INTERPRETATION: The findings are most consistent with hepatocellular carcinoma arising in a hepatocellular adenoma. The non-neoplastic liver lacks features of chronic hepatitis or cirrhosis.

SYNOPTIC SUMMARY

Procedure: Partial hepatectomy
Major hepatectomy (3 segments or more)

Specimen: Liver

Tumor Size: Greatest dimension: 14 cm

Tumor Focality: Solitary

Histologic Type: Hepatocellular carcinoma

Histologic Grade: GII: Moderately differentiated

Tumor Extension: Tumor involves a major branch of the portal vein

Margins: Parenchymal margin uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 7 mm

Lymphovascular Invasion:
Macroscopic Venous (Large Vessel Invasion (V): Present
Microscopic (Small Vessel) Invasion (L): Present

[page 3 of 4]
Pathologic Staging (pTNM):

Primary Tumor (pT): pT3b: Single tumor or multiple tumors of any size involving a major branch of the portal vein or hepatic vein

Regional Lymph Nodes (pN): pNX: Cannot be assessed

Pathologic Stage (AJCC 2009, 7th edition): Stage IIIA

Distant Metastasis (pM): Not applicable

Additional Pathologic Findings: Arises in adenoma

This electronic signature indicates that the pathologist has personally reviewed the available gross and/or microscopic material and has based the diagnosis on that evaluation.

Gross Specimen

Gross Specimen

Gross Specimen

Gross Specimen

Gross Description:

Received fresh, labeled with the patient's name and "liver tumor, stitch=inferior" is a 1300 gm, 18 x 15 x 8 cm portion of liver with a stitch designating inferior and a 2.5 x 0.8 x 0.3 cm portion of stomach with a staple line attached to the liver capsule. The staple line is removed and the resection margin of the stomach is inked blue. The serosal surface is tan-red and smooth. The resection margin is inked yellow and the specimen is sliced from inferior to superior to reveal a 17.3 x 14 x 8.5 cm heterogenous, well-circumscribed, multinodular tumor. The nodules range from 0.2 cm to 7 cm and are focally hemorrhagic and necrotic with scarring. The tumor abuts the serosa and is 1.2 cm to the closest resection margin. Multiple satellite nodules ranging from 0.1 cm to 1 cm are noted around the tumor. Minimal unremarkable liver parenchyma is present. The specimen is fixed overnight. Representative sections are submitted, as follows: cassettes #1-3=tumor to

[page 4 of 4]
resection margin, cassettes #4-16=sections from tumor (with cassettes #5-7=largest nodule and cassettes #8-9=hemorrhagic and scar area), cassette #17=sections from tumor, cassettes #18-19=tumor to adjacent liver parenchyma and cassette #20=uninvolved liver parenchyma. Sections from the stomach to the attached liver is submitted in cassette #21-22.

Summary of Stains Performed and Reviewed	Count
Amyloid A *	2
Amyloid A *	2
Beta Catenin *	2
Diastase PAS	1
Glutamine Synthetase *	2
Glypican-3 *	1
H&E, Recut, Level	10
Hepatitis B, core antigen *	1
Hepatitis B, surface antigen *	1
HSP-70 *	1
Negative Control *	3
Prussian Blue (Iron)	1
Reticulum, Gordon	2
Trichrome, Klatskin	1

*The immunohistochemical profile may include the use of Analyte Specific Reagents, or Research Agents, whose performance characteristics have not been established by the supplier. The histochemical tests were developed and their performance characteristics were determined by the supplier. It has not been cleared or approved by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary for this test. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is regulated under the Clinical Laboratory Improvements Amendments of 1988 (CLIA) as qualified to perform high complexity clinical testing. External and internal controls stained appropriately.

Summary of Tissue Submitted for Microscopic Examination

Block Detail

	# Blocks	Designation	#	Description
Part 1) LIVER TUMOR	48	[Undes]	(48)	(No Description)

END OF REPORT

Criteria	hw 12/17/13	Yes	No

Source: NCI Genomic Data Commons file 09c40fad-fa60-4296-b712-719e657b0d81 (TCGA-WX-AA47.473868C8-CFDF-42E6-B6DC-48A737697D07.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).